BEATAML1.0 case 2684 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/35245dfe-1a38-46db-9c45-541b6dbbc31d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Myeloid sarcoma: ICD-O-3 morphology code: 9930/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.7 years (6,839 days); Progression or recurrence: no.

Biospecimens (2 samples)
- Sample BA3296D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA3296R: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
